Gene-level copy-number profile of tumor specimen TCGA-ER-A3EV-06A from TCGA case TCGA-ER-A3EV, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 57.8 years (21,099 days).
Specimen TCGA-ER-A3EV-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.bb00469d-4c99-44ed-952d-6f06b8742fa5.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A3EV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d84c7e05-625b-4bbd-a83e-bcf117ec85a8

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 675; copy number 2: 7,084; copy number 3: 12,405; copy number 4: 28,591; copy number 5: 4,213; copy number 6: 1,350; copy number 7: 1,654; copy number 8: 345; copy number 9: 1,146; copy number 10: 132; copy number 11: 765; copy number 12: 76; copy number 13: 80; copy number 14: 264; copy number 15: 217; copy number 16: 60; copy number 18: 349; copy number 19: 68; copy number 20: 122; copy number 21: 42; copy number 27: 19; copy number 28: 74; copy number 29: 14; copy number 30: 32; copy number 32: 3; copy number 33: 17; copy number 35: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A3EV-06A-11D-A20B-01): tumor purity 0.63, ploidy 3.95, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,064,089–181,265,145, 3 genes: LINC00290, AC019235.1, LINC02500.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,493 genes in 40 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,782,671–152,985,500, 181 genes, copy number 18–20 (broad region; genes not listed).
- chr1:153,992,685–154,870,281, 36 genes, copy number 13 (within-gene range 5–19): NUP210L, AL358472.1, RNU6-179P, RPS7P2, MIR5698, TPM3, RN7SL431P, MIR190B, C1orf189, C1orf43, UBAP2L, SNORA58B, HAX1, AL354980.1, RNU6-239P, RNU6-121P, AL354980.2, AQP10, ATP8B2, RNU7-57P, AL162591.1, RPSAP17, IL6R-AS1, IL6R, PSMD8P1, SHE, AL162591.2, TDRD10, UBE2Q1, UBE2Q1-AS1, AL592078.2, CHRNB2, AL592078.1, ADAR, AL606500.1, KCNN3.
- chr1:155,335,268–155,563,162, 1 gene, copy number 18 (within-gene range 5–18): ASH1L.
- chr1:155,433,178–155,660,245, 9 genes, copy number 18: POU5F1P4, ASH1L-AS1, AL353807.4, DAP3P1, AL353807.1, AL353807.2, MSTO1, AL353807.3, AL353807.5.
- chr1:160,215,715–160,647,295, 16 genes, copy number 16 (within-gene range 2–16): DCAF8, AL139011.2, AL139011.1, RPSAP18, PEX19, COPA, SUMO1P3, Y_RNA, NCSTN, NHLH1, RNU4-42P, VANGL2, SLAMF6, AL138930.1, CD84, SLAMF1.
- chr1:161,399,409–161,422,424, 1 gene, copy number 18 (within-gene range 3–18): AL592295.4.
- chr1:161,403,409–163,923,873, 61 genes, copy number 18 (broad region; genes not listed).
- chr1:166,665,885–166,975,540, 8 genes, copy number 18 (within-gene range 2–18): FMO10P, RPL4P2, FMO11P, CNN2P10, POGK, TADA1, DUTP6, ILDR2.
- chr1:169,132,531–169,367,948, 2 genes, copy number 20 (within-gene range 2–20): NME7, Z99758.1.
- chr1:169,662,007–169,854,080, 1 gene, copy number 12 (within-gene range 2–12): C1orf112.
- chr1:169,722,640–174,160,165, 102 genes, copy number 9–33 (broad region; genes not listed).
- chr1:176,829,128–177,164,973, 3 genes, copy number 18: AL031290.1, ASTN1, MIR488.
- chr1:204,154,819–204,213,988, 4 genes, copy number 11–12 (within-gene range 4–12): REN, AL592114.2, KISS1, GOLT1A.
- chr1:204,346,776–204,728,106, 15 genes, copy number 15: AL592114.1, LINC00628, AL606489.1, AL606489.2, PPP1R15B, PIK3C2B, MDM4, AL512306.1, RNA5SP74, AL512306.3, LRRN2, AL512306.2, AL161793.1, RNA5SP75, AL161793.2.
- chr3:27,110,085–27,369,460, 1 gene, copy number 9 (within-gene range 6–9): NEK10.
- chr3:27,265,580–32,506,389, 62 genes, copy number 9–11 (broad region; genes not listed).
- chr4:54,376,002–54,859,241, 6 genes, copy number 9: AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358.
- chr6:167,607–13,287,843, 245 genes, copy number 9–21 (within-gene range 8–21) (broad region; genes not listed).
- chr6:15,243,923–15,522,042, 5 genes, copy number 16 (within-gene range 6–16): AL136162.1, JARID2, JARID2-AS1, RNU6-522P, RNU6-645P.
- chr6:16,129,086–17,737,556, 29 genes, copy number 12: MYLIP, MIR4639, AL021407.2, AL021407.1, MRPL42P2, RNU6-1114P, Y_RNA, GMPR, AL009031.1, ATXN1, ATXN1-AS1, AL137003.1, AL133405.2, AL133405.1, AL138740.1, STMND1, AL136305.1, RBM24, AL034372.1, CAP2, RPL7P26, SUMO2P13, AL138824.1, FAM8A1, NUP153, RNU6-190P, AL138724.1, RNA5SP204, Y_RNA.
- chr6:21,233,168–21,383,200, 3 genes, copy number 9: AL451080.1, AL031767.1, AL031767.2.
- chr6:24,126,186–39,030,792, 764 genes, copy number 11–18 (within-gene range 8–18) (broad region; genes not listed).
- chr6:39,314,698–39,322,968, 1 gene, copy number 9: KCNK16.
- chr6:39,353,747–39,354,172, 1 gene, copy number 9: AL136087.1.
- chr6:46,492,052–47,042,350, 12 genes, copy number 9: AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1.
- chr8:54,247,633–63,609,600, 140 genes, copy number 9–30 (broad region; genes not listed).
- chr8:66,562,175–81,635,662, 240 genes, copy number 11–35 (broad region; genes not listed).
- chr8:83,912,713–85,087,186, 11 genes, copy number 12–32: AC015522.1, TPM3P3, AC012400.1, RALYL, RNU6-1040P, PSMC2P2, AC009901.1, AC009901.2, ACTBP6, JCHAINP1, AC091175.1.
- chr11:70,862,790–70,896,305, 3 genes, copy number 13: SHANK2-AS3, MIR3664, AP003783.1.
- chr11:71,998,613–81,556,425, 246 genes, copy number 9–14 (broad region; genes not listed).
- chr11:81,842,435–81,987,813, 3 genes, copy number 14: AP002802.2, MIR4300, AP002802.1.
- chr11:92,748,732–96,514,748, 100 genes, copy number 9–21 (broad region; genes not listed).
- chr11:100,641,975–102,498,801, 30 genes, copy number 9–27: RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535, AP001527.1, AP001527.2, YAP1, AP000942.2, AP000942.1, AP000942.3, AP000942.4, RNU6-952P, AP000942.5, BIRC3, BIRC2, TMEM123, AP001830.1, AP001830.2.
- chr11:102,963,460–104,976,116, 26 genes, copy number 14–29: AP001486.3, AP001486.1, DCUN1D5, AP001486.2, DYNC2H1, AP002961.1, MTCO3P15, MTATP6P15, MTCO2P15, MTCO1P15, MTND2P26, MTND1P36, AP003461.1, AP002989.1, MIR4693, PDGFD, AP003043.1, DDI1, AP003304.1, LINC02552, AP001485.1, AP002004.1, CASP12, CASP4LP, CASP4, AP001153.1.
- chr11:105,092,469–105,982,092, 8 genes, copy number 19 (within-gene range 1–19): CARD17, CASP1P1, CARD18, OR2AL1P, AP003181.1, Metazoa_SRP, GRIA4, HSPD1P13.
- chr11:107,176,286–107,457,844, 4 genes, copy number 15: ASS1P13, AP000766.1, CWF19L2, SMARCE1P1.
- chr11:115,128,218–115,128,373, 1 gene, copy number 10: AP003179.1.
- chr11:115,659,168–115,661,417, 1 gene, copy number 15: AP000997.4.
- chr15:64,687,573–101,933,350, 985 genes, copy number 9–11 (broad region; genes not listed).
- chr19:28,065,267–34,229,515, 126 genes, copy number 9–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 675. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
